Somatic mutation profile of tumor specimen TCGA-ZG-A9LB-01A (aliquot TCGA-ZG-A9LB-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9LB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.4 years (26,447 days).
Specimen TCGA-ZG-A9LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ffb78a4-5efb-49a0-ae8e-25d910ea6d78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LB-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LB-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ceef183-873d-496a-85a1-82c35383836d

The open-access MAF lists 49 somatic variants for this specimen: 41 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Nonsense Mutation 3, Splice Region 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF4 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1264445313, COSV51956425, COSV99348000; called by muse, mutect2, varscan2
- CACNA1E | c.5897T>C p.L1966P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); catalogued as COSV100703238; called by muse, mutect2
- CCDC88B | c.3982C>T p.R1328W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758603220, COSV100105553; called by muse, varscan2
- COL13A1 | c.402G>A p.G134= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62570120; called by muse, mutect2, varscan2
- CTNNB1 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV100846271; called by muse, mutect2, varscan2
- DOT1L | c.3266G>A p.R1089Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs762399335, COSV101288703; called by muse, mutect2, varscan2
- FAT3 | c.12838G>A p.V4280M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53110551; called by muse, mutect2, varscan2
- FOXA1 | c.660C>G p.H220Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99163516; called by muse, mutect2, varscan2
- GAD2 | c.1525A>T p.I509F | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV99393436; called by muse, mutect2, varscan2
- GPR158 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372800397, COSV66283190; called by muse, mutect2, varscan2
- HMGCLL1 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99232393; called by muse, mutect2, varscan2
- HPD | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000130, COSV100000164; called by muse, mutect2, varscan2
- KIT | c.2755C>T p.Q919* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV55418140, COSV99854541; called by muse, mutect2, varscan2
- KRT25 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV56444377; called by muse, mutect2, varscan2
- LRRC23 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV99145231; called by muse, mutect2, varscan2
- MEFV | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs766608226, COSV99561007; called by mutect2, varscan2
- MYO9A | c.1406C>G p.A469G | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100613724; called by muse, mutect2
- NOMO1 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99814607; called by muse, mutect2
- NSD3 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 16/472 reads (3%) | catalogued as COSV100388720, COSV100389035; called by muse, mutect2
- OR10J3 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs150299321; called by muse, mutect2, varscan2
- PIK3C3 | c.2174dup p.Y725* | Nonsense Mutation (INS) | VAF 7/46 reads (15%) | catalogued as rs1449755492; called by mutect2, pindel, varscan2
- PLXNA4 | c.4475G>A p.R1492H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58103431; called by muse, mutect2, varscan2
- PTMS | c.113_115del p.V38del | In Frame Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs754481529; called by pindel, varscan2
- RAD18 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as rs775252068, COSV99368526; called by muse, mutect2, varscan2
- RBCK1 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs546711324, COSV62292198; called by mutect2, varscan2
- SAA2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs750654169, COSV99879352; called by muse, mutect2, varscan2
- SAMD4A | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs948578399, COSV51888319; called by muse, mutect2
- SLC12A9 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs756415501, COSV51933422; called by muse, mutect2, varscan2
- SNX5 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as rs761676504, COSV66698539; called by muse, mutect2, varscan2
- TAF1 | c.2003G>A p.G668E (on ENST00000373790 / NM_138923.4; = p.G689E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV52112816; called by muse, mutect2, varscan2
- THBS4 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100644326; called by muse, mutect2, varscan2
- THSD7B | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558902485, COSV55726737, COSV55751938; called by muse, mutect2, varscan2
- TRIP11 | c.2601A>C p.E867D | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970793; called by muse, mutect2, varscan2
- UBR4 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.931); catalogued as COSV100921081; called by muse, mutect2, varscan2
- UQCRC1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99178986; called by muse, mutect2, varscan2
- XKR4 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV59299789; called by muse, mutect2
- YIPF5 | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV50823067, COSV99188193; called by muse, mutect2, varscan2
- ZFYVE27 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100519311, COSV100519357; called by muse, mutect2, varscan2
- ZNF276 | c.800C>T p.T267M (on ENST00000443381 / NM_001113525.2; = p.T192M on NM_152287.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs766884816, COSV99235036; called by muse, mutect2, varscan2
- ZNF451 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs766325841, COSV62597193; called by mutect2, varscan2
- JMY | c.1416G>A p.A472= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs373926091; called by muse, mutect2, varscan2
- KCNH6 | c.1524C>T p.F508= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1333191899, COSV100121119; called by muse, mutect2, varscan2
- LTBP4 | c.4239G>A p.P1413= (on ENST00000308370 / NM_001042544.1; = p.P1376= on NM_003573.2) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs760319724, COSV52579576, COSV52588456; called by mutect2, varscan2
- MYCBPAP | c.1314C>A p.T438= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV100088394; called by muse, mutect2, varscan2
- SLC22A2 | c.411C>T p.T137= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1033640036, COSV100870996; called by muse, mutect2, varscan2
- TM2D3 | c.693G>A p.L231= (on ENST00000333202 / NM_078474.3; = p.L205= on NM_025141.3) | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs183173353, COSV100309815; called by muse, mutect2, varscan2
- YBX1 | c.732A>C p.R244= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100172125; called by muse, mutect2, varscan2
- ASIC2 | c.556-179371C>T | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as rs952150268, COSV99860351; called by muse, varscan2
